Somatic mutation profile of tumor specimen 0DPYE4 from CCDI case PBCEHM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (1,000 days).
Specimen 0DPYE4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b24ec50b-82c0-479f-91be-6a83cda782fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPYD7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9af829ce-6c0c-45a5-8a8b-e049c5262556

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX49 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201324570; called by muse, mutect2, varscan2
- OLFM1 | c.1099G>A p.V367M (on ENST00000371793 / NM_001282611.2; = p.V349M on NM_014279.5) | Missense Mutation (SNP) | VAF 146/317 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs950757823, COSV99423363; called by muse, mutect2, varscan2
- OTOF | c.5069C>T p.P1690L (on ENST00000272371 / NM_194248.3; = p.P923L on NM_004802.4) | Missense Mutation (SNP) | VAF 261/883 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs747707655; called by muse, mutect2, varscan2
- ATPAF2 | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 191/405 reads (47%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM135B | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 29/603 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PITPNM1 | c.3342_3342+9del p.X1114_splice | Splice Site (DEL) | VAF 71/584 reads (12%) | called by mutect2, pindel, varscan2
- TUT1 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 264/637 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNG8 | c.390C>A p.I130= | Silent (SNP) | VAF 228/3810 reads (6%) | called by muse, mutect2
- FCRL1 | c.279C>A p.S93= | Silent (SNP) | VAF 30/978 reads (3%) | called by muse, mutect2
- TNRC6C | c.3666G>T p.P1222= | Silent (SNP) | VAF 100/536 reads (19%) | called by muse, mutect2, varscan2
- AGAP3 | c.224-2096C>T | Intron (SNP) | VAF 17/34 reads (50%) | catalogued as rs773611115; called by muse, mutect2, varscan2
- MARK3 | c.778-84del | Intron (DEL) | VAF 45/125 reads (36%) | called by mutect2, pindel, varscan2
- SEC31B | c.2966-31G>A | Intron (SNP) | VAF 34/184 reads (18%) | catalogued as rs376242499; called by muse, varscan2
